Gene-level copy-number profile of tumor specimen TCGA-24-1548-01A from TCGA case TCGA-24-1548, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.3 years (20,945 days).
Specimen TCGA-24-1548-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.113a01ed-70f4-4c51-9b01-2c567aa5e9fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1548-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/30be42db-4191-4741-8c2f-0f8fe08269e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 1,368; copy number 2: 24,662; copy number 3: 20,116; copy number 4: 10,433; copy number 5: 541; copy number 6: 2,249; copy number 7: 315; copy number 8: 58; copy number 11: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-1548-01): tumor purity 0.88, ploidy 2.84, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:56,815,549–60,522,120, 39 genes (within-gene range 0–2): MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC008780.1, AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1, PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P.
- chr6:167,644,479–168,101,511, 14 genes (within-gene range 0–3): AL356123.1, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1.
- chr7:10,931,943–10,940,735, 2 genes: NDUFA4, AC007029.1.
- chr7:11,006,399–11,006,876, 1 gene: RPL23AP52.
- chr8:74,320,613–74,518,007, 3 genes (within-gene range 0–2): GDAP1, AC103952.1, Y_RNA.
- chr8:109,240,919–109,345,954, 3 genes (within-gene range 0–2): NUDCD1, AC021237.1, ENY2.
- chr22:31,837,238–31,837,298, 1 gene: RNU6-201P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,141 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,509,380–180,566,523, 2 genes, copy number 5: OVAAL, Y_RNA.
- chr3:66,997,168–91,513,775, 218 genes, copy number 6 (broad region; genes not listed).
- chr7:63,011,463–70,793,506, 220 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:109,959,218–159,233,377, 969 genes, copy number 6 (broad region; genes not listed).
- chr10:20,779,973–21,293,011, 1 gene, copy number 6 (within-gene range 4–6): NEBL.
- chr10:21,028,999–21,248,095, 5 genes, copy number 6: EIF4BP2, NPM1P30, NEBL-AS1, AL731547.1, LUZP4P1.
- chr12:66,767–8,830,947, 312 genes, copy number 6 (broad region; genes not listed).
- chr12:8,858,143–28,581,511, 415 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr12:80,402,178–80,680,273, 1 gene, copy number 6 (within-gene range 4–6): PTPRQ.
- chr19:8,520,778–8,732,160, 9 genes, copy number 6 (within-gene range 3–6): MYO1F, AC092316.1, ADAMTS10, AC130469.1, NFILZ, AC243312.1, ACTL9, OR2Z1, RPL23AP78.
- chr19:13,862,063–19,537,581, 310 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:22,501,699–40,348,527, 551 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr19:43,153,279–43,935,282, 41 genes, copy number 5: AC005392.1, PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11, CEACAMP4, AC005392.2, CD177, AC005392.3, CD177P1, TEX101, LYPD3, PHLDB3, ETHE1, ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP, IRGQ, ZNF576, SRRM5, ZNF428, CADM4, PLAUR, RN7SL368P, AC005622.1, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283, ZNF404, AC006213.6, AC006213.2, AC006213.7, AC006213.3, ZNF45.
- chr20:87,250–2,760,108, 87 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,368. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
